Gene-level copy-number profile of tumor specimen TCGA-66-2753-01A from TCGA case TCGA-66-2753, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69.8 years (25,506 days).
Specimen TCGA-66-2753-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.586655c9-32b0-4acf-8313-f3d2e9cbbb73.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2753-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0010eeff-8bda-4517-9140-b9bbbc0661df

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,073; copy number 2: 14,038; copy number 3: 11,116; copy number 4: 28,123; copy number 5: 2,419; copy number 6: 881; copy number 7: 780; copy number 8: 317; copy number 10: 307; copy number 12: 210; copy number 13: 500; copy number 15: 35; copy number 20: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-66-2753-01): tumor purity 0.39, ploidy 3.62, whole-genome doublings 1 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,071 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 12–13 (broad region; genes not listed).
- chr8:37,405,439–38,704,855, 53 genes, copy number 15–20: AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1.
- chr8:38,744,020–38,744,131, 1 gene, copy number 20: Y_RNA.
- chr20:42,072,752–55,075,140, 306 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr20:55,420,336–55,427,197, 1 gene, copy number 10: LINC01441.

Autosomal genes at a single copy (total copy number 1): 502. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
